Surgical pathology report (de-identified scan), TCGA case TCGA-EM-A2CT, project TCGA-THCA (Thyroid Carcinoma), tissue source site University Health Network, specimen TCGA-EM-A2CT-01A (Primary Tumor).

[page 1 of 3]
Surgical Pathology Consultation Report

Patient
Name:
MRN:
DOB:
Gender: F
HCN:
Ordering
MD:
Copy To:

Service:
Visit #:
Location:
Facility:

Accession #:
Collected:
Received:
Reported:

Specimen(s) Received

1. Parathyroid: Right Biopsy, Lower
2. Parathyroid :Right paratracheal node
3. Parathyroid :left lower parathyroid
4. Thyroid :Total Thyroid stitch upper pole left lobe

Diagnosis

1. No pathological diagnosis: Fibroadipose tissue (site listed as "parathyroid, right biopsy, lower") biopsy.
2. No pathological diagnosis: Lymph nodes, 3 (right paratracheal) biopsy
3. No pathological diagnosis: Parathyroid (left lower) biopsy.
4. Papillary carcinoma, 1.1 cm, oncocytic variant, right: Thyroid
No pathological diagnosis: Lymph nodes, 2
No pathological diagnosis: Parathyroids, 3 (right, left, and intrathyroidal right)
-Total thyroidectomy specimen.

Synoptic Data

Procedure: Total thyroidectomy
Received: Fresh
Specimen Integrity: Intact
Specimen Size: Right lobe:
5.0 cm
2.6 cm
1.4 cm
Left lobe:
4.2 cm
2.4 cm
1.2 cm

1 CD-0-3
carcinoma, papillary, follicular variant
#340/3
Site: thyroid, NOS C73.9
lw 6/18/11

[page 2 of 3]
	Isthmus +/- pyramidal lobe:
	2.2 cm
	1.5 cm
	0.8 cm
Specimen Weight:	15 g
Tumor Focality:	Unifocal
----- DOMINANT TUMOR -----	
Tumor Laterality:	Right lobe
Tumor Size:	Greatest dimension: 1.1 cm
	Additional dimension: 0.7 cm
	Additional dimension: 0.7 cm
Histologic Type:	Papillary carcinoma, oncocytic or oxyphilic variant
	Follicular architecture per TSS, follicular variant = 100 %
	Other architecture: trabecular
	Oncocytic or oxyphilic cytomorphology
Histologic Grade:	Not applicable
Margins:	Margins uninvolved by carcinoma
Tumor Capsule:	Partially encapsulated
Tumor Capsular Invasion:	Not identified
Lymph-Vascular Invasion:	Not identified
Perineural Invasion:	Not identified
Extrathyroidal Extension:	Not identified
TNM Descriptors:	Not applicable
Primary Tumor (pT):	pT1b: Tumor more than 1 cm but not more than 2 cm in greatest dimension, limited to the thyroid
Regional Lymph Nodes (pN):	pN0: No regional lymph node metastasis
	Number of regional lymph nodes examined: 5
	Number of regional lymph nodes involved: 0
Distant Metastasis (pM):	Not applicable
Additional Pathologic Findings:	Adenomatoid nodule(s) or Nodular follicular disease
	Parathyroid gland(s), within normal limits

*Pathologic Staging is based on AJCC/UICC TNM, 7th Edition

Electronically

verified by:

Gross Description

1. The specimen labeled with the patient's name and as "parathyroid: Right biopsy, lower" consists of a tiny piece of tissue that measures 0.3 x 0.2 x 0.1 cm. It is frozen for intraoperative consultation.

1A frozen section block resubmitted

2. The specimen labeled with the patient's name and as "right paratracheal node" consists of a piece of tissue that measures 1 x 0.5 x 0.4-cm. It is bisected and frozen for intraoperative consultation.

2A frozen section block resubmitted.

[page 3 of 3]
3. The specimen labeled with the patient's name and as "left lower parathyroid" consists of a tiny piece of tissue that measures 0.2 x 0.2 x 0.1 cm less than 0.1 cm. It is frozen for intraoperative consultation.

3A frozen section block resubmitted.

4. The specimen labeled with the patient's name and as "total thyroid stitch upper pole left lobe" consists of a thyroid gland that is oriented with a stitch and weighs 15 g. The right lobe measures 5.0 cm SI x 2.6 cm ML x 1.4 cm AP, the left lobe measures 4.2 cm SI x 2.4 cm ML x, 1.2 cm AP and the isthmus measures 2.2 cm SI x 1.5 cm ML x 0.8 cm AP. The external surfaces have fibrous adhesions. No parathyroid glands and/or lymph nodes are identified grossly. The external surface is painted with liquid bluing. The right lower lobe contains one tan delineated nodule that measures 0.9 cm SI x 0.7 cm ML x 0.7 cm AP. The remainder of the thyroid tissue is grossly unremarkable. Sections of the nodule and normal tissue are stored frozen. The remainder of the specimen is submitted as follows:

4A-K right lobe, superior to inferior

4L,M isthmus

4N-T left lobe, superior to inferior

Quick Section Diagnosis

1. ? Parathyroid (Right, lower): Dx QS1A, QS1A deeper: Technically difficult frozen section – fibrous tissue,

no parathyroid identified. Await

paraffins.

Dx QS 1A phoned to Dr.

2. Paratracheal lymph node (Right): Dx QS 2A: 1 (one) lymph node, negative for metastatic carcinoma.

Dx QS 2A phoned to Dr.

3. ? Parathyroid (Left, lower): Dx QS 3A: Parathyroid tissue.

Dx QS 3A phoned to Dr. ,

Source: NCI Genomic Data Commons file 962438b1-b7a4-4489-87f6-67641cf530a6 (TCGA-EM-A2CT.8EFA3E32-F06C-4DAC-8774-2D05ADE3C3F4.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).